Gene-level copy-number profile of tumor specimen TCGA-44-6778-01A from TCGA case TCGA-44-6778, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.5 years (21,725 days).
Specimen TCGA-44-6778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.090b0e22-c7b1-40a0-ae5a-1cfe6fb93679.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6778-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4bbe83ca-3288-4cd6-8556-b6fdcb497b38

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 836; copy number 2: 19,464; copy number 3: 11,634; copy number 4: 19,692; copy number 5: 3,347; copy number 6: 4,056; copy number 7: 456; copy number 8: 87; copy number 9: 87; copy number 11: 63; copy number 13: 7; copy number 15: 45; copy number 28: 6; copy number 29: 24; copy number 35: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-6778-01A-11D-1854-01): tumor purity 0.25, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 238 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,067,279–151,401,937, 73 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr6:19,323,428–19,839,080, 1 gene, copy number 13 (within-gene range 4–13): LNC-LBCS.
- chr6:19,438,283–19,894,214, 6 genes, copy number 13: RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1.
- chr6:20,401,879–23,857,646, 33 genes, copy number 9–29 (within-gene range 8–29): E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2.
- chr6:26,172,059–27,084,147, 51 genes, copy number 15–35: H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9, H3C8, H2AC10P, H2BC10, H4C8, H3C9P, AL021917.1, BTN3A2, BTN2A2, BTN3A1, BTN2A3P, BTN3A3, BTN2A1, BTN1A1P1, BTN1A1, RNU6-502P, HCG11, HMGN4, AL121936.1, ABT1, AL513548.3, AL513548.2, ZNF322, AL513548.4, AL513548.1, GUSBP2, POM121L6P, LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P.
- chr6:39,104,063–39,115,186, 2 genes, copy number 29: SAYSD1, ANKRD18EP.
- chr6:102,078,872–102,079,555, 1 gene, copy number 11: AP002530.1.
- chr18:21,981,121–25,818,532, 71 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 299. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
